Somatic mutation profile of tumor specimen MP2PRT-PAPBLF-TMP1-A (aliquot MP2PRT-PAPBLF-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PAPBLF, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,473 days).
Specimen MP2PRT-PAPBLF-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 767ef7e7-be77-4089-90bc-fec189e47ba4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPBLF-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPBLF-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6f2d197-269b-40d9-9f4f-24c9a7f623fe

The open-access MAF lists 63 somatic variants for this specimen: 48 protein-altering or splice-affecting, 11 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 11, Nonsense Mutation 6, Intron 3, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXO1 | c.65C>G p.S22W | Missense Mutation (SNP) | VAF 112/653 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV65426970; called by muse, mutect2, varscan2
- A1CF | c.1196G>A p.R399H (on ENST00000373993 / NM_138932.2; = p.R391H on NM_014576.4) | Missense Mutation (SNP) | VAF 75/285 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as rs149597685; called by muse, mutect2, varscan2
- ARHGAP5 | c.3263C>T p.S1088L | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757296733; called by muse, mutect2
- BTBD2 | c.910G>C p.E304Q | Missense Mutation (SNP) | VAF 47/374 reads (13%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.457); catalogued as rs143346219; called by muse, mutect2, varscan2
- BTK | c.1764G>T p.W588C | Missense Mutation (SNP) | VAF 89/96 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM040387, CM066745, COSV58124566; called by muse, mutect2, varscan2
- C12orf4 | c.1620C>G p.F540L | Missense Mutation (SNP) | VAF 26/181 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54207964; called by muse, mutect2, varscan2
- C9orf40 | c.524C>T p.T175I | Missense Mutation (SNP) | VAF 99/272 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.259); catalogued as COSV100964956; called by muse, mutect2, varscan2
- DENND2C | c.551C>A p.S184* | Nonsense Mutation (SNP) | VAF 66/225 reads (29%) | catalogued as COSV67920237; called by muse, mutect2, varscan2
- DIS3 | c.2267C>T p.S756F | Missense Mutation (SNP) | VAF 28/296 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1489870875; called by muse, mutect2
- DLGAP1 | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 105/427 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1315959306, COSV59781676; called by muse, mutect2, varscan2
- DNAH7 | c.5567C>T p.S1856F | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV56758155; called by muse, mutect2
- DYNC2H1 | c.3271G>C p.D1091H | Missense Mutation (SNP) | VAF 7/145 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as rs1405104332, COSV100519134; called by muse, mutect2
- FEZF1 | c.1233G>C p.R411S | Missense Mutation (SNP) | VAF 34/337 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV58658266; called by muse, mutect2, varscan2
- GAB4 | c.500C>G p.S167* | Nonsense Mutation (SNP) | VAF 23/306 reads (8%) | catalogued as COSV68753806; called by muse, mutect2
- HELB | c.995C>T p.S332L | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV56076452; called by muse, mutect2
- HOXD8 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 16/378 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1400240845; called by muse, mutect2
- KDM2B | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 14/447 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65638226; called by muse, mutect2
- OR10H2 | c.193G>A p.V65I | Missense Mutation (SNP) | VAF 224/531 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.03); catalogued as rs772844697, COSV59946866; called by muse, mutect2, varscan2
- PCDH15 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 27/264 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs192813057, COSV57279849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHF12 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV52018198; called by muse, mutect2, varscan2
- PPP1R3E | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 92/602 reads (15%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.646); catalogued as rs983572006; called by muse, mutect2, varscan2
- RBMXL3 | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 16/330 reads (5%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.363); catalogued as COSV100406877; called by muse, mutect2
- RYR3 | c.3349G>A p.D1117N | Missense Mutation (SNP) | VAF 23/384 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.299); catalogued as rs373688734; called by muse, mutect2
- SENP7 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 94/205 reads (46%) | catalogued as rs1262515165, COSV100053231; called by muse, mutect2, varscan2
- SNTG1 | c.296T>A p.L99H | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52448785; called by muse, mutect2, varscan2
- TPRX1 | c.206C>T p.T69M | Missense Mutation (SNP) | VAF 35/506 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs764017560, COSV59115475; called by muse, mutect2
- UNC13C | c.1225C>G p.L409V | Missense Mutation (SNP) | VAF 29/278 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.192); catalogued as rs764983407; called by muse, mutect2, varscan2
- AFF3 | c.3146C>G p.S1049* | Nonsense Mutation (SNP) | VAF 20/334 reads (6%) | called by muse, mutect2
- ARFGEF3 | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 12/384 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.194); called by muse, mutect2
- BSN | c.2731G>C p.E911Q | Missense Mutation (SNP) | VAF 67/364 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- CBX6 | c.365A>G p.D122G | Missense Mutation (SNP) | VAF 130/465 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDH16 | c.530C>A p.P177Q | Missense Mutation (SNP) | VAF 35/442 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.439); called by muse, mutect2
- CHST2 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 47/425 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EHBP1L1 | c.3595_3603del p.R1199_D1201del | In Frame Del (DEL) | VAF 66/424 reads (16%) | called by mutect2, varscan2
- FOXL2 | c.201C>G p.I67M | Missense Mutation (SNP) | VAF 17/621 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIK5 | c.2519_2520insTTCTTAGGGA p.V841Sfs*2 | Nonsense Mutation (INS) | VAF 49/250 reads (20%) | called by mutect2, pindel, varscan2
- KIAA0100 | c.4586C>T p.S1529L | Missense Mutation (SNP) | VAF 33/216 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NLRP10 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 16/322 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.108); called by muse, mutect2
- NPRL3 | c.72C>G p.F24L | Missense Mutation (SNP) | VAF 27/571 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- NSD1 | c.2192C>G p.S731C | Missense Mutation (SNP) | VAF 32/408 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); called by muse, mutect2
- OPTN | c.87C>A p.H29Q | Missense Mutation (SNP) | VAF 15/466 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.251); called by muse, mutect2
- PLG | c.1711C>T p.Q571* | Nonsense Mutation (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- PTGDR | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 33/402 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2
- PTH2R | c.202G>C p.D68H | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO1B3 | c.902C>A p.T301K | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.081); called by muse, mutect2
- SPEN | c.8874G>C p.K2958N | Missense Mutation (SNP) | VAF 28/566 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2
- TAS2R13 | c.693G>C p.L231F | Missense Mutation (SNP) | VAF 24/322 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2
- TMC7 | c.501G>C p.L167F | Missense Mutation (SNP) | VAF 20/531 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- ADRA2A | c.675C>T p.L225= | Silent (SNP) | VAF 32/356 reads (9%) | catalogued as rs773495210; called by muse, mutect2
- ANK3 | c.2445G>A p.L815= | Silent (SNP) | VAF 25/317 reads (8%) | called by muse, mutect2
- ARF5 | c.411C>T p.S137= | Silent (SNP) | VAF 26/321 reads (8%) | catalogued as rs775287559, COSV99133758; called by muse, mutect2
- ATP13A2 | c.1593G>A p.L531= | Silent (SNP) | VAF 54/365 reads (15%) | called by muse, mutect2, varscan2
- BSN | c.5874G>A p.Q1958= | Silent (SNP) | VAF 67/384 reads (17%) | called by muse, mutect2, varscan2
- CROCC | c.4890G>A p.E1630= | Silent (SNP) | VAF 29/288 reads (10%) | catalogued as rs1276984256; called by muse, mutect2, varscan2
- GPR179 | c.1950C>T p.D650= (on ENST00000621958; = p.D649= on NM_001004334.4) | Silent (SNP) | VAF 34/554 reads (6%) | catalogued as rs372049950; ClinVar: uncertain significance; called by muse, mutect2
- GREB1L | c.1462C>T p.L488= | Silent (SNP) | VAF 47/292 reads (16%) | called by muse, mutect2, varscan2
- MYO5A | c.2160G>A p.L720= | Silent (SNP) | VAF 26/234 reads (11%) | called by muse, mutect2, varscan2
- SUSD3 | c.396G>A p.V132= | Silent (SNP) | VAF 14/286 reads (5%) | catalogued as COSV100968846; called by muse, mutect2
- TMED4 | c.96C>T p.F32= | Silent (SNP) | VAF 50/363 reads (14%) | catalogued as rs201894102, COSV56941883; called by muse, mutect2, varscan2
- ABI3BP | c.1576+10750G>A | Intron (SNP) | VAF 59/227 reads (26%) | catalogued as COSV52539971; called by muse, mutect2, varscan2
- CPLANE1 | c.*86C>G | 3'UTR (SNP) | VAF 30/209 reads (14%) | called by muse, mutect2, varscan2
- LSP1 | c.54-13399G>A | Intron (SNP) | VAF 40/443 reads (9%) | catalogued as rs1044635385; called by muse, mutect2
- SLCO1B3-SLCO1B7 | c.1866-15216C>G | Intron (SNP) | VAF 13/175 reads (7%) | called by muse, mutect2
